Somatic mutation profile of tumor specimen ALCH-B3C4-TTP1-A (aliquot ALCH-B3C4-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3C4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 54.2 years (19,791 days).
Specimen ALCH-B3C4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4621004-daa1-4063-9ce0-670d84e6f3c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3C4-NB1-A (Blood Derived Normal), aliquot ALCH-B3C4-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf50f18b-051b-4d89-b407-5451e30cf16a

The open-access MAF lists 179 somatic variants for this specimen: 120 protein-altering or splice-affecting, 32 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 32, Intron 17, Nonsense Mutation 7, RNA 3, Splice Region 3, Splice Site 3, 3'UTR 3, In Frame Del 2, 5'Flank 2, 5'UTR 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.840A>C p.R280S | Missense Mutation (SNP) | VAF 109/682 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs1567547687, CM136794, COSV52678283, COSV52782181, COSV52801834, COSV53205654; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS7 | c.4309C>T p.R1437C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs757341667, COSV101183028; called by mutect2, varscan2
- AFF3 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100418106; called by muse, mutect2, varscan2
- ATPAF1 | c.689G>A p.R230Q (on ENST00000574428; = p.R253Q on NM_022745.4) | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as rs375918153; called by muse, mutect2
- BIRC6 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs994276054; called by muse, mutect2
- CD163 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); catalogued as COSV100776065; called by muse, mutect2
- CR1 | c.3167C>G p.T1056R | Missense Mutation (SNP) | VAF 49/721 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.451); catalogued as COSV65456422; called by muse, mutect2
- DHX36 | c.2578T>C p.Y860H | Missense Mutation (SNP) | VAF 20/415 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as rs768118881; called by muse, mutect2
- EPS8L2 | c.2017G>C p.E673Q | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV59350482; called by muse, mutect2, varscan2
- ESPL1 | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.145); catalogued as rs775291881, COSV57764013; called by muse, mutect2, varscan2
- FBXW5 | c.352-6G>A | Splice Region (SNP) | VAF 77/249 reads (31%) | catalogued as rs374535247; called by muse, mutect2, varscan2
- FGF11 | c.553A>G p.N185D | Missense Mutation (SNP) | VAF 45/411 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs1477081619; called by muse, mutect2, varscan2
- GAS6 | c.489G>C p.E163D | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1398184065; called by muse, mutect2
- H3C2 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 71/478 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV52517730, COSV52518686, COSV99451691; called by muse, mutect2, varscan2
- IP6K1 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV100391369, COSV58663074; called by muse, varscan2
- KBTBD4 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 49/319 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1382630188; called by muse, mutect2, varscan2
- KLK5 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1456257630; called by muse, mutect2
- LPCAT1 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.06); catalogued as rs1289721390; called by muse, mutect2
- LRP2 | c.11201C>G p.P3734R | Missense Mutation (SNP) | VAF 102/848 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55581217; called by muse, mutect2, varscan2
- LTBP4 | c.712G>T p.E238* (on ENST00000308370 / NM_001042544.1; = p.E201* on NM_003573.2) | Nonsense Mutation (SNP) | VAF 31/242 reads (13%) | catalogued as COSV52576639; called by muse, mutect2, varscan2
- NLRP9 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 112/350 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.123); catalogued as rs762121597, COSV100242862; called by muse, mutect2, varscan2
- NPNT | c.1093C>G p.P365A | Missense Mutation (SNP) | VAF 66/260 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1360150809; called by muse, mutect2, varscan2
- OR7D2 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100712982; called by muse, mutect2, varscan2
- OR7G1 | c.847C>G p.Q283E | Missense Mutation (SNP) | VAF 43/378 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs1242684557; called by muse, mutect2, varscan2
- POLR1G | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs749264193; called by muse, mutect2, varscan2
- PPP1R12B | c.2668C>G p.L890V | Missense Mutation (SNP) | VAF 51/420 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs764614330, COSV51790514; called by muse, mutect2, varscan2
- RBFOX2 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 20/738 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV63857999; called by muse, mutect2
- RNF207 | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as rs780758468, COSV59474702; called by muse, mutect2, varscan2
- RNF31 | c.1771G>C p.E591Q | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as COSV53758661; called by muse, mutect2, varscan2
- RUBCN | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 82/954 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99584877; called by muse, mutect2
- SCO2 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs375383752; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHANK1 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 46/298 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1285568957; called by muse, mutect2, varscan2
- SLC18A1 | c.921G>A p.G307= | Splice Region (SNP) | VAF 17/90 reads (19%) | catalogued as rs1258011881; called by muse, mutect2, varscan2
- SSX2IP | c.1780G>A p.G594S | Missense Mutation (SNP) | VAF 32/496 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.045); catalogued as rs1026956182; called by muse, mutect2
- TMEM235 | c.178C>A p.R60S | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); catalogued as rs1043240548; called by muse, mutect2, varscan2
- TTN | c.50137G>C p.E16713Q (on ENST00000591111; = p.E9289Q on NM_003319.4) | Missense Mutation (SNP) | VAF 94/661 reads (14%) | PolyPhen benign (0.189); catalogued as rs1559697777; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP34 | c.5656G>C p.D1886H | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV68406696; called by muse, mutect2
- ZDHHC21 | c.28G>C p.D10H | Missense Mutation (SNP) | VAF 349/992 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66613179; called by muse, mutect2, varscan2
- ABCC8 | c.3278C>A p.A1093D | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by mutect2, varscan2
- ANKRD18B | c.1279G>C p.E427Q | Missense Mutation (SNP) | VAF 113/322 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- ANKRD27 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 54/694 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.132); called by muse, mutect2
- ANPEP | c.2233G>C p.E745Q | Missense Mutation (SNP) | VAF 47/319 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ARHGAP31 | c.1915C>G p.L639V | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2
- CAPN3 | c.1731G>C p.K577N | Missense Mutation (SNP) | VAF 58/368 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- CCDC168 | c.13451G>C p.G4484A | Missense Mutation (SNP) | VAF 86/662 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CNOT1 | c.2579C>T p.P860L | Missense Mutation (SNP) | VAF 64/510 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DDX10 | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 20/546 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDX41 | c.288G>C p.E96D | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- DOCK1 | c.1489-7C>G | Splice Region (SNP) | VAF 68/492 reads (14%) | called by muse, mutect2, varscan2
- EIF5B | c.2437G>C p.D813H | Missense Mutation (SNP) | VAF 49/438 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EPHA10 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.697); called by muse, mutect2
- EYA4 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 70/1014 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2
- FAT1 | c.10366_10377del p.G3456_V3459del | In Frame Del (DEL) | VAF 12/116 reads (10%) | called by mutect2, pindel
- FLRT1 | c.107T>C p.F36S | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- FOLH1 | c.964A>T p.S322C | Missense Mutation (SNP) | VAF 38/612 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.116); called by muse, mutect2
- FOXL2NB | c.341G>C p.S114T | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.028); called by muse, mutect2
- FYN | c.1042G>C p.G348R | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FZD6 | c.929C>G p.A310G | Missense Mutation (SNP) | VAF 148/1357 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GJD4 | c.727T>C p.S243P | Missense Mutation (SNP) | VAF 9/221 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- HECTD2 | c.2167G>A p.D723N | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- HERC2 | c.8081C>G p.S2694* | Nonsense Mutation (SNP) | VAF 38/452 reads (8%) | called by muse, mutect2
- HIP1R | c.1964-2A>C p.X655_splice | Splice Site (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- HNRNPL | c.1455C>G p.F485L | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- HOXA4 | c.91G>T p.G31C | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- HPCAL1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- IL20RB | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- JMJD7-PLA2G4B | c.423G>C p.Q141H | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- KLHL1 | c.2182A>G p.T728A | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.526); called by mutect2, varscan2
- KLHL38 | c.1216A>C p.S406R | Missense Mutation (SNP) | VAF 34/307 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- KRIT1 | c.2107G>T p.E703* | Nonsense Mutation (SNP) | VAF 28/384 reads (7%) | called by muse, mutect2
- KRTAP19-1 | c.158A>T p.Y53F | Missense Mutation (SNP) | VAF 103/839 reads (12%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- LAMP2 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 26/620 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.36); called by muse, mutect2
- LRP2 | c.12362C>A p.P4121H | Missense Mutation (SNP) | VAF 50/560 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2
- LRRC8E | c.1741C>G p.L581V | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- MAP2K7 | c.1168G>A p.V390M | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- MATK | c.892C>T p.Q298* (on ENST00000310132 / NM_139355.3; = p.Q299* on NM_002378.4) | Nonsense Mutation (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2
- MROH7 | c.2629A>G p.I877V | Missense Mutation (SNP) | VAF 62/403 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MS4A7 | c.263C>A p.P88Q | Missense Mutation (SNP) | VAF 12/398 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- NADSYN1 | c.666+1G>T p.X222_splice | Splice Site (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- NSUN4 | c.213G>C p.Q71H | Missense Mutation (SNP) | VAF 52/381 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- NWD1 | c.3302C>T p.A1101V | Missense Mutation (SNP) | VAF 40/329 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- OR4A47 | c.498C>A p.F166L | Missense Mutation (SNP) | VAF 46/653 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR6N1 | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OVOL1 | c.459_479del p.K153_D160delinsN | In Frame Del (DEL) | VAF 26/289 reads (9%) | called by mutect2, pindel
- PASD1 | c.914A>G p.E305G | Missense Mutation (SNP) | VAF 48/758 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); called by muse, mutect2
- PDE7B | c.517C>G p.H173D | Missense Mutation (SNP) | VAF 44/536 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PFDN5 | c.200C>A p.T67K | Missense Mutation (SNP) | VAF 27/494 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- PHB | c.380T>G p.L127R | Missense Mutation (SNP) | VAF 15/295 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PLXNA2 | c.3802G>C p.D1268H | Missense Mutation (SNP) | VAF 40/591 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- PRAG1 | c.3427C>T p.H1143Y | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRIMPOL | c.1615C>G p.L539V | Missense Mutation (SNP) | VAF 46/383 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- PXYLP1 | c.798G>C p.L266F | Missense Mutation (SNP) | VAF 46/345 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- REV1 | c.3536T>G p.I1179S | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- RFPL2 | c.79C>A p.H27N | Missense Mutation (SNP) | VAF 27/273 reads (10%) | PolyPhen benign (0.107); called by muse, mutect2, varscan2
- RNF32 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 41/220 reads (19%) | called by muse, mutect2, varscan2
- RPGRIP1L | c.1822G>C p.E608Q | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR3 | c.4200G>C p.Q1400H | Missense Mutation (SNP) | VAF 61/481 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- SIPA1L1 | c.853C>G p.R285G | Missense Mutation (SNP) | VAF 48/502 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); called by muse, mutect2
- SLC35E1 | c.357G>C p.K119N | Missense Mutation (SNP) | VAF 42/392 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPATS2 | c.1615C>G p.Q539E | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SVIL | c.4285A>T p.T1429S (on ENST00000355867 / NM_021738.3; = p.T1003S on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TESC | c.412-1G>A p.X138_splice | Splice Site (SNP) | VAF 22/114 reads (19%) | called by muse, mutect2, varscan2
- TEX101 | c.508G>C p.E170Q (on ENST00000598265 / NM_001130011.3; = p.E188Q on NM_031451.4) | Missense Mutation (SNP) | VAF 65/294 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TLN2 | c.5482A>G p.M1828V | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- TMEM45B | c.249G>C p.K83N | Missense Mutation (SNP) | VAF 137/791 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TPSD1 | c.436A>C p.T146P | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTN | c.52010C>T p.S17337L (on ENST00000591111; = p.S9913L on NM_003319.4) | Missense Mutation (SNP) | VAF 109/674 reads (16%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TUBGCP6 | c.2008C>G p.Q670E | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- UBE2Q1 | c.1054A>C p.M352L | Missense Mutation (SNP) | VAF 57/559 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- UNC79 | c.7606C>G p.L2536V (on ENST00000393151 / NM_001346218.2; = p.L2359V on NM_020818.5) | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- USP34 | c.3045G>A p.W1015* | Nonsense Mutation (SNP) | VAF 42/168 reads (25%) | called by muse, mutect2, varscan2
- VWA5B1 | c.3208G>C p.E1070Q (on ENST00000375079; = p.E1065Q on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.494); called by mutect2, varscan2
- WDR3 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 98/951 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- WDR54 | c.569C>G p.S190* | Nonsense Mutation (SNP) | VAF 103/587 reads (18%) | called by muse, mutect2, varscan2
- WDR74 | c.1_11del p.M1_?4 | Frame Shift Del (DEL) | VAF 14/120 reads (12%) | called by mutect2, pindel
- ZFYVE9 | c.2980G>T p.D994Y | Missense Mutation (SNP) | VAF 56/853 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZKSCAN5 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 80/358 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ZNF518B | c.3181G>C p.E1061Q | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNFX1 | c.3601C>G p.R1201G | Missense Mutation (SNP) | VAF 98/458 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNRF4 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CLDN1 | c.123G>A p.V41= | Silent (SNP) | VAF 38/578 reads (7%) | called by muse, mutect2
- DTNB | c.1485G>A p.R495= | Silent (SNP) | VAF 119/540 reads (22%) | called by muse, mutect2, varscan2
- EFCAB3 | c.1182A>G p.L394= | Silent (SNP) | VAF 52/348 reads (15%) | catalogued as rs1331723709; called by muse, mutect2, varscan2
- EGFR | c.213G>A p.Q71= | Silent (SNP) | VAF 128/853 reads (15%) | called by muse, mutect2, varscan2
- EIF3G | c.729C>T p.V243= | Silent (SNP) | VAF 33/173 reads (19%) | called by muse, mutect2, varscan2
- FRMD7 | c.954G>A p.L318= | Silent (SNP) | VAF 117/815 reads (14%) | called by muse, mutect2, varscan2
- GOLGA4 | c.703T>C p.L235= | Silent (SNP) | VAF 82/497 reads (16%) | called by muse, mutect2, varscan2
- INPPL1 | c.1809C>T p.F603= | Silent (SNP) | VAF 28/285 reads (10%) | catalogued as COSV53356120; called by muse, mutect2, varscan2
- IRX2 | c.1143C>T p.P381= | Silent (SNP) | VAF 25/233 reads (11%) | catalogued as rs767823988; called by muse, mutect2, varscan2
- JUND | c.840C>T p.I280= | Silent (SNP) | VAF 77/658 reads (12%) | catalogued as rs1292070305; called by muse, mutect2, varscan2
- KCNQ4 | c.1323C>T p.R441= | Silent (SNP) | VAF 32/200 reads (16%) | called by muse, mutect2, varscan2
- KRT25 | c.1239C>G p.V413= | Silent (SNP) | VAF 21/440 reads (5%) | catalogued as rs1369323080; called by muse, mutect2
- MAMLD1 | c.465G>C p.L155= | Silent (SNP) | VAF 78/738 reads (11%) | called by muse, mutect2, varscan2
- MEN1 | c.1425G>T p.P475= | Silent (SNP) | VAF 28/204 reads (14%) | catalogued as COSV53641026; called by muse, mutect2, varscan2
- MLNR | c.726G>A p.L242= | Silent (SNP) | VAF 21/135 reads (16%) | called by muse, mutect2, varscan2
- MUC16 | c.20208C>T p.I6736= | Silent (SNP) | VAF 28/320 reads (9%) | catalogued as COSV67456101; called by muse, mutect2
- PLCL1 | c.1962G>A p.L654= | Silent (SNP) | VAF 20/253 reads (8%) | called by muse, mutect2
- PRSS27 | c.708C>G p.L236= | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- RNF32 | c.957C>A p.L319= | Silent (SNP) | VAF 78/451 reads (17%) | called by muse, mutect2, varscan2
- SOGA1 | c.684C>T p.L228= | Silent (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2, varscan2
- SPDL1 | c.61C>T p.L21= | Silent (SNP) | VAF 60/410 reads (15%) | catalogued as rs1047001; called by muse, mutect2, varscan2
- STAB1 | c.1947C>A p.I649= | Silent (SNP) | VAF 17/135 reads (13%) | called by muse, mutect2, varscan2
- STAP1 | c.756C>G p.V252= | Silent (SNP) | VAF 20/187 reads (11%) | called by muse, mutect2, varscan2
- TACC3 | c.1491G>A p.S497= | Silent (SNP) | VAF 45/215 reads (21%) | catalogued as rs769951751; called by muse, mutect2, varscan2
- TNFRSF8 | c.876A>T p.S292= | Silent (SNP) | VAF 55/411 reads (13%) | called by muse, mutect2, varscan2
- TRMT11 | c.36C>T p.L12= | Silent (SNP) | VAF 90/285 reads (32%) | called by muse, mutect2, varscan2
- VCAM1 | c.789T>C p.D263= | Silent (SNP) | VAF 87/747 reads (12%) | called by muse, mutect2, varscan2
- WDR77 | c.147G>C p.L49= | Silent (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- ZC3H7A | c.1650T>C p.N550= | Silent (SNP) | VAF 68/464 reads (15%) | called by muse, mutect2, varscan2
- ZNF426 | c.379A>C p.R127= | Silent (SNP) | VAF 42/594 reads (7%) | catalogued as rs1410542310; called by muse, mutect2
- ZNF469 | c.7830G>C p.L2610= (on ENST00000437464; = p.L2638= on NM_001367624.2) | Silent (SNP) | VAF 85/537 reads (16%) | called by muse, mutect2, varscan2
- ZNF729 | c.3723A>G p.K1241= | Silent (SNP) | VAF 22/420 reads (5%) | catalogued as rs907943219; called by muse, mutect2
- AHR | c.1160+36T>A | Intron (SNP) | VAF 44/364 reads (12%) | called by muse, mutect2, varscan2
- AL359878.1 | n.390G>C | RNA (SNP) | VAF 42/656 reads (6%) | called by muse, mutect2
- AL450344.3 | chr6:150600006 G>A | 5'Flank (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- ARHGEF4 | c.1921+13C>A | Intron (SNP) | VAF 16/392 reads (4%) | called by muse, mutect2
- CAGE1 | c.2113-933_2113-913delinsA | Intron (DEL) | VAF 74/404 reads (18%) | called by pindel, varscan2*
- CFL2 | c.4-96G>C | Intron (SNP) | VAF 157/1208 reads (13%) | called by muse, mutect2, varscan2
- CHTF8 | chr16:69132557 C>G | 5'Flank (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- COL20A1 | c.3295-114C>T | Intron (SNP) | VAF 5/72 reads (7%) | catalogued as rs994375188, COSV58921731; called by muse, mutect2
- CPNE9 | c.109+16A>G | Intron (SNP) | VAF 33/350 reads (9%) | called by muse, mutect2
- FAM136A | c.87+369G>A | Intron (SNP) | VAF 54/457 reads (12%) | called by muse, mutect2, varscan2
- FMNL1 | c.*14C>G | 3'UTR (SNP) | VAF 22/113 reads (19%) | called by muse, mutect2, varscan2
- GRM7 | c.2698+10933G>C | Intron (SNP) | VAF 32/281 reads (11%) | called by muse, mutect2, varscan2
- GYS1 | c.*981C>G | 3'UTR (SNP) | VAF 66/377 reads (18%) | called by muse, mutect2, varscan2
- IGHV3-35 | c.-11A>T | 5'UTR (SNP) | VAF 109/423 reads (26%) | called by muse, mutect2, varscan2
- INTS9 | c.1564-54G>C | Intron (SNP) | VAF 22/154 reads (14%) | called by muse, mutect2, varscan2
- LINC01036 | n.293C>A | RNA (SNP) | VAF 75/775 reads (10%) | called by muse, mutect2
- LMO3 | c.*2C>T | 3'UTR (SNP) | VAF 57/388 reads (15%) | catalogued as COSV53783309; called by muse, mutect2, varscan2
- PIP5K1B | c.69+1565G>A | Intron (SNP) | VAF 55/564 reads (10%) | called by muse, mutect2
- PRPF39 | c.451-209G>C | Intron (SNP) | VAF 23/310 reads (7%) | called by muse, mutect2
- RCC1 | c.-228-175_-228-149del | Intron (DEL) | VAF 70/827 reads (8%) | called by mutect2, pindel
- RXYLT1 | c.-7G>C | 5'UTR (SNP) | VAF 37/341 reads (11%) | called by muse, mutect2, varscan2
- SGSM3 | c.1629+17G>A | Intron (SNP) | VAF 7/41 reads (17%) | called by muse, varscan2
- SLC44A2 | c.2015-321G>C | Intron (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- SSPOP | n.6759C>G | RNA (SNP) | VAF 16/402 reads (4%) | called by muse, mutect2
- TBX1 | c.1009+407G>A | Intron (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- TNNI3K | c.1772+5200C>A | Intron (SNP) | VAF 26/684 reads (4%) | called by muse, mutect2
- ZNF606 | c.-52+474G>T | Intron (SNP) | VAF 26/520 reads (5%) | called by muse, mutect2
